CCDI case PBCJIB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/d81ab4a2-0e36-41fb-b8df-c4d70b9e558a

Demographics
Sex at birth: male; Race: white.

Biospecimens (3 samples)
- Sample 0DTNVG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTNWC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DTNX8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
